Somatic mutation profile of tumor specimen MP2PRT-PAVCFS-TMP1-A (aliquot MP2PRT-PAVCFS-TMP1-A-1-0-D-A81Q-36) from MP2PRT case MP2PRT-PAVCFS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,108 days).
Specimen MP2PRT-PAVCFS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e95594b1-a694-40a0-bde5-d47e5ba0401e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVCFS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVCFS-NB1-A-1-0-D-A81Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2a63eed0-ea3f-422e-9d04-e2d8f62efa44

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, RNA 2, Silent 2, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHB2 | c.2863C>T p.R955W (on ENST00000400191 / NM_001309193.2; = p.R956W on NM_004442.7) | Missense Mutation (SNP) | VAF 116/319 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748534693, COSV65863572; called by muse, mutect2, varscan2
- FAM71E2 | c.1795G>A p.V599M | Missense Mutation (SNP) | VAF 98/287 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as rs1288936943; called by muse, mutect2, varscan2
- FAT2 | c.10804G>A p.V3602I | Missense Mutation (SNP) | VAF 194/526 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs549157480, COSV55823482; called by muse, mutect2, varscan2
- FOXJ2 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 110/340 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs1013961740; called by muse, mutect2, varscan2
- TLR4 | c.543C>A p.D181E (on ENST00000355622 / NM_138554.5; = p.D141E on NM_003266.4) | Missense Mutation (SNP) | VAF 98/353 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs763536574, COSV62923861; called by muse, mutect2, varscan2
- ALOX15B | c.215_239del p.A72Gfs*15 | Frame Shift Del (DEL) | VAF 194/685 reads (28%) | called by mutect2, pindel, varscan2
- MC1R | c.437T>C p.I146T | Missense Mutation (SNP) | VAF 238/686 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- SPTBN5 | c.1211A>G p.E404G | Missense Mutation (SNP) | VAF 165/548 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- STAT5B | c.1283A>T p.D428V | Missense Mutation (SNP) | VAF 95/306 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, varscan2
- CDH4 | c.585C>T p.S195= | Silent (SNP) | VAF 104/310 reads (34%) | catalogued as rs374076466, COSV100848438; called by muse, mutect2, varscan2
- ZNF701 | c.762T>C p.I254= (on ENST00000301093; = p.I188= on NM_018260.3) | Silent (SNP) | VAF 131/359 reads (36%) | called by muse, mutect2, varscan2
- IGKV1D-8 | chr2:90221385 del CACA | 3'Flank (DEL) | VAF 17/45 reads (38%) | called by pindel*, varscan2
- LINC02881 | n.256G>A | RNA (SNP) | VAF 154/525 reads (29%) | catalogued as rs941117282; called by muse, mutect2, varscan2
- XIST | n.8397T>C | RNA (SNP) | VAF 56/203 reads (28%) | called by muse, mutect2, varscan2
